Somatic mutation profile of tumor specimen MMRF_2214_1_BM_CD138pos (aliquot MMRF_2214_1_BM_CD138pos_T1_KHS5U_L08691) from MMRF case MMRF_2214, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.9 years (27,714 days).
Specimen MMRF_2214_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85450d5c-977e-4713-9ba7-aa9b2391a6a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2214_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2214_1_PB_Whole_C3_KHS5U_L08690; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27ddf795-d95a-41df-9b77-aff2346b163e

The open-access MAF lists 111 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 22, Silent 14, Intron 13, 5'UTR 4, 5'Flank 4, 3'Flank 2, Nonsense Mutation 2, Splice Region 2, Splice Site 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 85/175 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD40 | c.294A>T p.E98D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs199734034; called by muse, mutect2, varscan2
- ARHGAP22 | c.1369G>A p.G457S | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as rs748738151; called by muse, mutect2, varscan2
- COL20A1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs749535969, COSV58920416, COSV99045407; called by muse, mutect2, varscan2
- CRISPLD1 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 79/190 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51551479; called by muse, mutect2, varscan2
- DCST1 | c.779G>C p.R260P | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV55061839; called by muse, mutect2, varscan2
- DLG5 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141294188; called by muse, mutect2
- EPHA1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs45447297, COSV51977736; called by muse, mutect2, varscan2
- ESX1 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV65424475; called by muse, mutect2, varscan2
- GIGYF2 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1361124254, COSV65246799; called by muse, mutect2, varscan2
- GPATCH8 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100132757; called by muse, varscan2
- GPR101 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV53238534, COSV99981240; called by muse, mutect2
- IGHV2-70 | c.302T>A p.L101H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs188731942; called by muse, varscan2
- IGHV2-70 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as rs557763852; called by muse, varscan2
- IGKV4-1 | c.151T>G p.Y51D | Missense Mutation (SNP) | VAF 42/42 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.184); catalogued as rs141709704; called by muse, varscan2
- IGKV4-1 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 46/46 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs760776890; called by muse, varscan2
- IQCE | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs776623235; called by muse, mutect2, varscan2
- KDM6B | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 38/79 reads (48%) | catalogued as COSV54679612; called by muse, mutect2, varscan2
- KRT83 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs139360978; ClinVar: benign; called by muse, mutect2, varscan2
- OTUD4 | c.731C>G p.S244C (on ENST00000447906 / NM_001366057.1; = p.S179C on NM_001102653.1) | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV56850471; called by muse, mutect2, varscan2
- PTPRS | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV53615442, COSV53627345; called by muse, mutect2, varscan2
- RABL3 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); catalogued as rs1409633248, COSV56336618; called by muse, mutect2, varscan2
- TACC3 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1361216939; called by muse, mutect2, varscan2
- USP43 | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1216468129; called by muse, mutect2, varscan2
- WT1 | c.1160A>C p.N387T | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); catalogued as rs748864758, COSV60069448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B2 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CATSPERG | c.2930+6C>A | Splice Region (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- CCDC158 | c.3185C>T p.T1062I | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- DTX1 | c.1191_1192del p.R398Ifs*10 | Frame Shift Del (DEL) | VAF 25/70 reads (36%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.13472A>T p.N4491I | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM118B | c.432G>C p.Q144H | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM83D | c.1096T>G p.S366A | Missense Mutation (SNP) | VAF 101/104 reads (97%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- GPATCH8 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- HORMAD2 | c.19T>G p.S7A | Missense Mutation (SNP) | VAF 125/249 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IGHV1-2 | c.46G>C p.G16R | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, varscan2
- KERA | c.484T>A p.F162I | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNOP1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT82 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- LARGE1 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- LARP6 | c.1461C>A p.S487R | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NCOA7 | c.2677G>T p.E893* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- NRXN1 | c.1135-2A>C p.X379_splice | Splice Site (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- PTPRS | c.2204C>A p.T735K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ROBO3 | c.2492T>C p.M831T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA5A | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SLC9A3R2 | c.214-8C>A | Splice Region (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5507_5545del p.L1836_G1848del | In Frame Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel
- UROD | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS37A | c.764A>C p.Q255P | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- WNK2 | c.2755A>G p.M919V | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, varscan2
- XPR1 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF616 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- BLOC1S2 | c.162G>A p.G54= | Silent (SNP) | VAF 56/150 reads (37%) | called by muse, mutect2, varscan2
- CCDC180 | c.687C>A p.S229= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as COSV63836703; called by muse, mutect2, varscan2
- CRYGN | c.201C>T p.G67= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as rs763283061, COSV61563688; called by muse, mutect2, varscan2
- EPHA6 | c.45G>A p.P15= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV67586862; called by muse, mutect2
- KCNJ9 | c.549C>T p.D183= | Silent (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- MLX | c.849G>A p.R283= | Silent (SNP) | VAF 27/27 reads (100%) | called by muse, varscan2
- NKX2-1 | c.1071C>T p.Y357= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs566854717, CM1310884; called by muse, mutect2, varscan2
- NLRP12 | c.780G>A p.T260= | Silent (SNP) | VAF 69/220 reads (31%) | catalogued as rs148038630; called by muse, mutect2, varscan2
- PARD6G | c.105C>T p.D35= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.1278C>A p.P426= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as rs756414475; called by muse, mutect2, varscan2
- TRIOBP | c.3783C>T p.T1261= | Silent (SNP) | VAF 72/133 reads (54%) | catalogued as rs371220515; called by muse, mutect2, varscan2
- TUBGCP6 | c.90G>C p.R30= | Silent (SNP) | VAF 39/91 reads (43%) | called by muse, mutect2, varscan2
- USP39 | c.1680C>G p.T560= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- ZNF275 | c.858C>T p.I286= | Silent (SNP) | VAF 50/50 reads (100%) | called by mutect2, varscan2
- ARNT2 | c.*2313C>A | 3'UTR (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
- ASTN2 | c.3355+6174C>T | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2
- CACNA2D4 | c.1351+97G>A | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- CALM1 | c.*1249T>C | 3'UTR (SNP) | VAF 31/53 reads (58%) | catalogued as rs994848297; called by muse, mutect2, varscan2
- CALY | c.246+362C>G | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- CASC15 | chr6:22146963 G>A | 5'Flank (SNP) | VAF 8/9 reads (89%) | catalogued as rs562156523; called by muse, varscan2
- CCR5 | c.*1712del | 3'UTR (DEL) | VAF 15/60 reads (25%) | catalogued as rs939905165; called by mutect2, varscan2
- CCSER1 | c.2011-34064A>C | Intron (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- CCT5 | c.*962G>A | 3'UTR (SNP) | VAF 38/55 reads (69%) | called by muse, mutect2, varscan2
- CYP4F3 | c.199-1712G>A | Intron (SNP) | VAF 83/253 reads (33%) | catalogued as rs765496128, COSV99657712, COSV99658155; called by muse, mutect2, varscan2
- DDX21 | c.*903A>G | 3'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- DIO2 | c.*3104A>C | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- EGLN3 | c.357+977C>T | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- FAF1 | c.1870-10553G>T | Intron (SNP) | VAF 19/39 reads (49%) | catalogued as rs779003533; called by mutect2, varscan2
- FOXI2 | chr10:127736753 C>T | 5'Flank (SNP) | VAF 33/91 reads (36%) | catalogued as rs1313728378; called by muse, mutect2, varscan2
- FOXO3B | c.*74G>A | 3'UTR (SNP) | VAF 32/73 reads (44%) | catalogued as COSV53383036; called by muse, mutect2, varscan2
- GNG4 | c.*795G>A | 3'UTR (SNP) | VAF 11/27 reads (41%) | catalogued as rs1383664450; called by muse, mutect2
- GREM1 | c.-2+450G>T | Intron (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- IMP3 | c.-54G>A | 5'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- ISL1 | c.*540T>C | 3'UTR (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- IST1 | c.*1037C>G | 3'UTR (SNP) | VAF 78/138 reads (57%) | called by muse, mutect2, varscan2
- ITGA5 | c.*55C>G | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- KCNS1 | c.*1931T>C | 3'UTR (SNP) | VAF 30/30 reads (100%) | called by muse, mutect2, varscan2
- MCF2L | c.170-12947C>T | Intron (SNP) | VAF 11/20 reads (55%) | catalogued as rs1418335214; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851324 C>G | 5'Flank (SNP) | VAF 47/118 reads (40%) | catalogued as rs572738324; called by muse, mutect2, varscan2
- MPHOSPH8 | c.*56G>C | 3'UTR (SNP) | VAF 63/154 reads (41%) | called by muse, mutect2, varscan2
- MX2 | c.-6C>A | 5'UTR (SNP) | VAF 71/159 reads (45%) | called by muse, mutect2, varscan2
- MYOCD | chr17:12763803 G>T | 3'Flank (SNP) | VAF 32/66 reads (48%) | called by muse, mutect2, varscan2
- NPL | c.231-2858G>A | Intron (SNP) | VAF 13/25 reads (52%) | catalogued as rs1201039624; called by muse, mutect2, varscan2
- PHF21B | c.*613C>T | 3'UTR (SNP) | VAF 22/38 reads (58%) | catalogued as rs1333601360; called by muse, mutect2, varscan2
- PIM2 | c.*294_*296del | 3'UTR (DEL) | VAF 22/24 reads (92%) | called by pindel, varscan2
- PLG | c.*21C>T | 3'UTR (SNP) | VAF 30/96 reads (31%) | catalogued as rs756939818; called by muse, mutect2, varscan2
- PRSS40A | n.318-729A>T | Intron (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.*726G>C | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- RABL3 | chr3:120682249 G>A | 3'Flank (SNP) | VAF 64/164 reads (39%) | catalogued as rs969923554, COSV99381455, COSV99381491; called by muse, mutect2, varscan2
- RBMS1 | c.-394T>C | 5'UTR (SNP) | VAF 25/50 reads (50%) | catalogued as rs1370043095; called by muse, mutect2, varscan2
- RPL27A | c.*3579A>G | 3'UTR (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- RPS18 | c.3+62G>A | Intron (SNP) | VAF 103/246 reads (42%) | called by muse, mutect2, varscan2
- SBK1 | c.*299C>T | 3'UTR (SNP) | VAF 7/48 reads (15%) | catalogued as rs1473131759; called by mutect2, varscan2
- SRRM5 | c.-261G>A | 5'UTR (SNP) | VAF 41/127 reads (32%) | called by muse, mutect2, varscan2
- TCF25 | c.1629-28G>C | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2
- TMEM33 | c.*2946G>A | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- TRDN | c.*1579C>T | 3'UTR (SNP) | VAF 25/27 reads (93%) | catalogued as COSV62130112; called by muse, mutect2, varscan2
- UBE2I | chr16:1308807 G>T | 5'Flank (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- ZNF462 | c.*1710G>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
